TCGA case TCGA-B0-5712 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/514af471-31d2-43fa-88dc-8639a5e97181

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Alive.

Diagnoses (2)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 68.4 years (24,988 days); Year of diagnosis: 2004; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease; Days to treatment start: 21 days; Days to treatment end: 28 days; Treatment dose: 2,400 cGy; Number of fractions: 6; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Zoledronic Acid; Days to treatment start: 177 days; Treatment outcome: Stable Disease.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 70.4 years (25,713 days); Days to diagnosis: 725 days (2.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.

Follow-up (3 entries)
- Day 725 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 2,722 days (7.5 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day 2,438.

Molecular and laboratory tests
- Hemoglobin: Low.
- Leukocytes: Normal.
- Calcium: Normal.
- Platelets: Normal.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-B0-5712-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.7; Intermediate dimension: 0.5; Shortest dimension: 0.2.
  Slide TCGA-B0-5712-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25.
  Slide TCGA-B0-5712-01A-01-TS1: Section location: Top; Percent tumor cells: 82; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 18.
- Sample TCGA-B0-5712-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-B0-5712-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.6; Intermediate dimension: 0.8; Shortest dimension: 0.4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Hemoglobin level: Low.
- Drug treatment: Pharmaceutical therapy drug name: Zometa.
- Radiation treatment: Therapy regimen: Progression.
- Follow-up form: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,722 days; disease-specific survival: no event (censored), 2,722 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 725 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-B0-5712-01A-11D-1668-01): tumor purity 0.72, ploidy 2.01, whole-genome doublings 0.
